Somatic mutation profile of tumor specimen 79b60f32-6cca-4cb6-9a1e-22a3ac (aliquot 79b60f32-6cca-4cb6-9a1e-22a3ac_D6) from CPTAC case 04OV053, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV.
Specimen 79b60f32-6cca-4cb6-9a1e-22a3ac: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15b1a9ea-3dc9-4a67-97c3-9cc9e50f911c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 46a46133-bb15-4d38-8a83-15c186 (Blood Derived Normal), aliquot 46a46133-bb15-4d38-8a83-15c186_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96c4dd62-5506-49d5-9a6e-2bf6d4ec7d94

The open-access MAF lists 138 somatic variants for this specimen: 91 protein-altering or splice-affecting, 30 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 30, Intron 5, 5'Flank 4, Nonsense Mutation 3, 5'UTR 3, RNA 2, 3'UTR 2, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAA2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs772972462; called by muse, mutect2, varscan2
- AHNAK | c.5425G>A p.D1809N | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as COSV57227404; called by muse, mutect2, varscan2
- ALDH7A1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs181287032, COSV63160706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEND3 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 223/289 reads (77%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs782336685; called by muse, mutect2, varscan2
- BTN3A2 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs751467291; called by muse, mutect2
- C16orf86 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376801265, COSV99708390; called by muse, varscan2
- CBY2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.176); catalogued as rs781536192, COSV60117510; called by muse, mutect2, varscan2
- CCDC33 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs775127307; called by muse, mutect2, varscan2
- CD177 | c.1243T>C p.S415P | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs1568445723; called by muse, mutect2, varscan2
- CYP2F1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1441435776; called by muse, mutect2, varscan2
- DAB2IP | c.3032C>G p.A1011G (on ENST00000408936; = p.A983G on NM_032552.3) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.223); catalogued as COSV52258004; called by muse, mutect2, varscan2
- DAZL | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99167504; called by muse, mutect2, varscan2
- DUSP22 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148279164; called by muse, mutect2
- FBXO15 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.191); catalogued as rs1453637594, COSV54043464; called by muse, mutect2, varscan2
- GJC1 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs747790250, COSV57910609; called by muse, varscan2
- GJC1 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 137/219 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395187; called by muse, mutect2, varscan2
- GPT | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 178/970 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs562794201; called by muse, varscan2
- GTF3C4 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV60140409; called by muse, mutect2, varscan2
- IMMT | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 78/804 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1453330097, COSV54479602; called by muse, mutect2
- KBTBD7 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 168/672 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as rs1309846186; called by muse, varscan2
- KPNA6 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101012557, COSV65361872; called by muse, mutect2, varscan2
- LIMCH1 | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58302253; called by muse, mutect2
- LRRC53 | c.1029T>A p.H343Q | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1329463845; called by muse, mutect2, varscan2
- MCM6 | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs1016677087; called by muse, mutect2, varscan2
- MUC16 | c.29276C>T p.S9759L | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs868342937, COSV67475605; called by muse, mutect2, varscan2
- NEFM | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 55/463 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as rs1351441260; called by muse, mutect2, varscan2
- NSD1 | c.5441del p.P1814Lfs*7 | Frame Shift Del (DEL) | VAF 38/204 reads (19%) | catalogued as COSV61776125; called by mutect2, varscan2
- OCRL | c.1044C>G p.I348M | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV63980441; called by muse, mutect2, varscan2
- OR14K1 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 138/502 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV51721806; called by muse, mutect2, varscan2
- OR5M3 | c.747C>G p.F249L | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56565639; called by muse, mutect2, varscan2
- PADI6 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs754193133, COSV100639874; called by muse, mutect2, varscan2
- PASD1 | c.2194G>T p.G732* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV64854776; called by muse, mutect2, varscan2
- PCDH15 | c.2057T>A p.L686Q | Missense Mutation (SNP) | VAF 131/235 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57290982, COSV57307750; called by muse, mutect2, varscan2
- PCDH19 | c.3046G>A p.A1016T (on ENST00000373034 / NM_001184880.2; = p.A968T on NM_020766.3) | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV55257182; called by mutect2, varscan2
- PCDHA6 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 109/481 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as rs199941722, COSV65358691; called by muse, mutect2, varscan2
- PHF20L1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs146835449; called by muse, mutect2, varscan2
- PIK3R5 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs143224779; called by muse, mutect2
- PPP2R2C | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs776449314, COSV59447500; called by muse, mutect2, varscan2
- PROSER2 | c.1304C>G p.S435W | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV104374965; called by muse, mutect2, varscan2
- SBNO1 | c.3899G>A p.R1300H (on ENST00000420886; = p.R1299H on NM_018183.5) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs756146079, COSV57345947; called by muse, mutect2, varscan2
- SLC25A47 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772715544; called by muse, mutect2
- SUPT6H | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457006465; called by muse, mutect2, varscan2
- SV2C | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs13153247, COSV59215070; called by muse, varscan2
- TRIM25 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as rs150231506, COSV57543224; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3202G>C p.E1068Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs1445170265; called by muse, mutect2, varscan2
- VPS26C | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs762842167; called by muse, mutect2, varscan2
- ZMYM4 | c.2541C>G p.F847L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV58913616; called by muse, mutect2, varscan2
- ZNF717 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 12/288 reads (4%) | catalogued as rs1417140810, COSV101277551; called by muse, mutect2
- AIRE | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 63/333 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AK9 | c.2624A>G p.E875G | Missense Mutation (SNP) | VAF 82/115 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.165); called by muse, varscan2
- ARFGEF2 | c.3421C>G p.H1141D | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ASXL2 | c.315G>C p.Q105H | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.075); called by muse, varscan2
- CEP78 | c.1331G>T p.S444I (on ENST00000424347 / NM_001349840.2; = p.S445I on NM_032171.3) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CFAP46 | c.5207G>A p.S1736N | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL4A1 | c.3175A>T p.I1059F | Missense Mutation (SNP) | VAF 126/493 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- COL6A5 | c.5248G>C p.E1750Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.07); called by muse, mutect2
- DNAJB14 | c.326A>C p.Y109S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DPYD | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.6938A>T p.Q2313L | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2
- FEZ1 | c.618G>C p.Q206H | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); called by muse, mutect2
- GABRE | c.1087T>A p.F363I | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- GLIS2 | c.657G>A p.R219= | Splice Region (SNP) | VAF 76/373 reads (20%) | called by muse, mutect2, varscan2
- GRIN3A | c.1312G>C p.A438P | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- IGKV1-12 | c.169T>G p.W57G | Missense Mutation (SNP) | VAF 68/1317 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IRF6 | c.103C>G p.R35G | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- KANK2 | c.2102G>T p.G701V (on ENST00000586659 / NM_001379562.1; = p.G709V on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA0319 | c.2517G>C p.R839S | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KNTC1 | c.1376A>T p.K459M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LDLRAD2 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- LSR | c.116C>A p.A39E | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MFAP5 | c.393A>T p.E131D | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MSN | c.74C>A p.T25N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- NEB | c.577G>T p.V193F | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, varscan2
- OR52R1 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 60/502 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLK2 | c.548G>C p.R183P | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROB1 | c.1223G>C p.R408P | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.605); called by muse, mutect2
- RASGEF1A | c.1306A>T p.I436F | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- REV1 | c.3734G>T p.G1245V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RGS14 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RNF213 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 100/368 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SCAP | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 78/413 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEC31A | c.1882-1G>T p.X628_splice (on ENST00000355196 / NM_001318120.1; = p.X589_splice on NM_016211.4) | Splice Site (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- SHISA9 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SIGLEC1 | c.2185T>C p.C729R | Missense Mutation (SNP) | VAF 108/689 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by mutect2, varscan2
- SLC25A32 | c.250G>T p.G84* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2, varscan2
- SLC2A13 | c.1351dup p.C451Lfs*14 | Frame Shift Ins (INS) | VAF 42/231 reads (18%) | called by mutect2, pindel, varscan2
- STK17B | c.103A>C p.T35P | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- STPG2 | c.902C>G p.A301G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TBX2 | c.1104C>A p.S368R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.095); called by muse, mutect2
- UNC80 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 70/351 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF831 | c.4573A>C p.T1525P | Missense Mutation (SNP) | VAF 61/530 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- AASS | c.1077A>T p.T359= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- ARHGAP4 | c.2433G>T p.V811= | Silent (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- CNKSR2 | c.183C>A p.G61= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- CUX2 | c.1236G>A p.K412= | Silent (SNP) | VAF 45/369 reads (12%) | called by muse, mutect2, varscan2
- DPYSL4 | c.468C>G p.V156= | Silent (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- EPHA5 | c.468T>C p.F156= | Silent (SNP) | VAF 68/305 reads (22%) | catalogued as rs151252926; called by muse, mutect2, varscan2
- GABRA2 | c.1095C>T p.N365= | Silent (SNP) | VAF 77/135 reads (57%) | catalogued as rs199645306, COSV100734761; called by muse, mutect2, varscan2
- GPAA1 | c.1668G>A p.T556= | Silent (SNP) | VAF 82/396 reads (21%) | catalogued as rs782585123; called by muse, mutect2, varscan2
- HNRNPA1 | c.96C>T p.S32= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- IGKV3D-11 | c.324T>C p.C108= | Silent (SNP) | VAF 53/402 reads (13%) | catalogued as rs574033830; called by muse, mutect2, varscan2
- IL9R | c.246C>G p.L82= | Silent (SNP) | VAF 35/237 reads (15%) | catalogued as rs769962448; called by muse, mutect2, varscan2
- ITPR1 | c.3963G>A p.G1321= (on ENST00000354582; = p.G1306= on NM_002222.7) | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV100233020; called by muse, mutect2, varscan2
- KCNAB3 | c.1062C>T p.R354= | Silent (SNP) | VAF 60/218 reads (28%) | catalogued as rs751064457; called by muse, mutect2, varscan2
- KCNK10 | c.1341C>T p.F447= | Silent (SNP) | VAF 78/454 reads (17%) | catalogued as rs1012048390, COSV56639613; called by muse, mutect2, varscan2
- MARCHF2 | c.384C>T p.D128= | Silent (SNP) | VAF 59/233 reads (25%) | catalogued as rs775968699; called by muse, mutect2, varscan2
- MATR3 | c.2508A>G p.K836= | Silent (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- MESP2 | c.1074G>C p.P358= | Silent (SNP) | VAF 60/250 reads (24%) | catalogued as rs763376959; called by muse, mutect2, varscan2
- NEFM | c.612C>T p.R204= | Silent (SNP) | VAF 170/373 reads (46%) | catalogued as COSV55333842; called by muse, mutect2, varscan2
- NOS1 | c.1395C>T p.T465= | Silent (SNP) | VAF 39/240 reads (16%) | called by muse, mutect2, varscan2
- OOSP2 | c.183G>C p.R61= | Silent (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- PDLIM7 | c.468G>A p.R156= | Silent (SNP) | VAF 55/301 reads (18%) | catalogued as rs1406240880; called by muse, mutect2, varscan2
- PLXNA2 | c.495G>A p.T165= | Silent (SNP) | VAF 127/824 reads (15%) | catalogued as rs373183654; called by muse, mutect2, varscan2
- RFX4 | c.1752C>T p.S584= (on ENST00000392842 / NM_213594.3; = p.S490= on NM_032491.6) | Silent (SNP) | VAF 64/219 reads (29%) | catalogued as rs77713501; called by muse, mutect2, varscan2
- RICTOR | c.1155A>G p.P385= | Silent (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- SH2D3C | c.1143G>A p.T381= (on ENST00000314830 / NM_170600.3; = p.T224= on NM_005489.4) | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs760750693; called by muse, mutect2, varscan2
- SLC26A1 | c.636C>T p.L212= | Silent (SNP) | VAF 67/369 reads (18%) | catalogued as rs1247616681, COSV56103484; called by muse, mutect2, varscan2
- SYT9 | c.1380C>T p.N460= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as rs1322610114, COSV59616673, COSV59623882; called by muse, mutect2, varscan2
- TBC1D23 | c.984G>A p.A328= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs778155479; called by mutect2, varscan2
- TNFSF11 | c.951T>C p.D317= | Silent (SNP) | VAF 45/192 reads (23%) | called by muse, mutect2, varscan2
- ZNF668 | c.285G>A p.T95= | Silent (SNP) | VAF 53/309 reads (17%) | catalogued as rs760468531; called by muse, mutect2, varscan2
- AC244394.2 | n.1654C>A | RNA (SNP) | VAF 48/157 reads (31%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840445 C>T | 5'Flank (SNP) | VAF 115/980 reads (12%) | catalogued as rs747367482, COSV100005407; called by muse, mutect2, varscan2
- BNIP2 | c.-178C>G | 5'UTR (SNP) | VAF 15/85 reads (18%) | catalogued as rs1461564996; called by muse, mutect2, varscan2
- C2CD6 | c.1582-3467C>G | Intron (SNP) | VAF 9/225 reads (4%) | called by muse, mutect2
- C4B | chr6:32011274 A>C | 5'Flank (SNP) | VAF 36/843 reads (4%) | called by muse, mutect2
- CBR1 | c.397+98C>G | Intron (SNP) | VAF 40/264 reads (15%) | called by muse, mutect2, varscan2
- CDIPT | c.-95C>T | 5'UTR (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- CNN2 | chr19:1026588 C>G | 5'Flank (SNP) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- EDIL3 | c.1137+12076G>A | Intron (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- EMC4 | c.201+185G>C | Intron (SNP) | VAF 42/137 reads (31%) | called by muse, mutect2, varscan2
- FHL1 | c.*771A>G | 3'UTR (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- HK3 | c.260-58G>A | Intron (SNP) | VAF 69/391 reads (18%) | catalogued as rs745874084; called by muse, mutect2, varscan2
- LINC02610 | n.2805C>T | RNA (SNP) | VAF 13/75 reads (17%) | catalogued as rs979257197; called by muse, mutect2, varscan2
- POLR2H | c.-37C>T | 5'UTR (SNP) | VAF 95/280 reads (34%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25072573 G>T | 3'Flank (SNP) | VAF 55/440 reads (13%) | called by muse, mutect2, varscan2
- WDFY4 | c.*246G>A | 3'UTR (SNP) | VAF 36/107 reads (34%) | called by muse, mutect2, varscan2
- WSB2 | chr12:118062169 A>G | 5'Flank (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
